CCDI case PBBLPZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/cbdc6384-ec02-401e-9e65-1c7c960f1822

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 16.8 years (6,133 days).

Biospecimens (3 samples)
- Sample 0DE3GU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DE3H9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DE3HH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
